Gene-level copy-number profile of tumor specimen TCGA-A2-A04P-01A from TCGA case TCGA-A2-A04P, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 36.2 years (13,238 days).
Specimen TCGA-A2-A04P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.514e30c9-fe93-4d52-a31f-9e771c71d300.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A04P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/68720344-2294-44a3-99f8-7b73bd39cc77

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 1,164; copy number 2: 15,783; copy number 3: 12,808; copy number 4: 12,741; copy number 5: 10,563; copy number 6: 3,660; copy number 7: 1,680; copy number 8: 777; copy number 9: 383; copy number 10: 175; copy number 11: 3; copy number 12: 3; copy number 73: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A04P-01A-31D-A036-01): tumor purity 0.6, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:39,973,128–41,723,512, 36 genes: AC098591.3, PABPC1P1, KRT18P25, AC098591.2, N4BP2, RNU6-1112P, AC098591.1, AC095057.1, AC095057.3, AC095057.4, RHOH, AC095057.2, LINC02265, CHRNA9, RNU7-74P, RBM47, AC098869.2, AC098869.1, MIR4802, AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P.
- chr5:94,567,461–94,739,436, 6 genes (within-gene range 0–2): MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1.
- chr5:96,247,776–96,434,143, 2 genes: AC099509.2, PCSK1.
- chr14:79,611,418–79,791,263, 3 genes: AC008056.2, AC008056.3, AC008056.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17,230 genes in 73 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–145,996,579, 99 genes, copy number 5 (broad region; genes not listed).
- chr1:220,528,136–248,919,946, 684 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:38,814–30,210,307, 519 genes, copy number 5 (broad region; genes not listed).
- chr2:30,677,762–38,231,651, 110 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:45,388,680–66,433,470, 330 genes, copy number 6–9 (broad region; genes not listed).
- chr2:136,765,545–148,595,328, 110 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:11,745–10,321,112, 139 genes, copy number 5 (broad region; genes not listed).
- chr3:78,525,101–109,977,767, 291 genes, copy number 5 (broad region; genes not listed).
- chr3:149,517,235–179,267,002, 422 genes, copy number 5–73 (within-gene range 4–73) (broad region; genes not listed).
- chr3:187,291,272–198,222,513, 238 genes, copy number 5 (broad region; genes not listed).
- chr4:42,281,830–76,234,536, 492 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr4:104,653,874–148,444,698, 559 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:58,198–16,440,081, 285 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:167,607–33,804,003, 1,014 genes, copy number 6–7 (broad region; genes not listed).
- chr6:130,839,347–163,363,463, 545 genes, copy number 5–10 (within-gene range 3–14) (broad region; genes not listed).
- chr7:70,972–23,532,041, 375 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:40,135,005–70,793,506, 576 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:72,879,365–130,262,770, 1,032 genes, copy number 5–6 (within-gene range 3–7) (broad region; genes not listed).
- chr8:46,028,804–54,420,725, 128 genes, copy number 5 (broad region; genes not listed).
- chr8:115,408,496–145,066,685, 507 genes, copy number 5–11 (broad region; genes not listed).
- chr9:14,475–16,061,663, 212 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr9:60,914,407–98,708,935, 677 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr10:4,024,903–38,360,098, 596 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:32,829,927–56,820,422, 467 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:69,048,932–73,865,133, 162 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:5,948,877–10,329,608, 242 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:14,365,632–34,249,958, 348 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr12:79,574,979–103,578,947, 361 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:18,333,726–22,499,749, 295 genes, copy number 5–7 (broad region; genes not listed).
- chr16:46,469,341–53,504,411, 177 genes, copy number 5 (broad region; genes not listed).
- chr16:70,480,568–74,368,240, 100 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr16:75,409,332–90,222,851, 395 genes, copy number 5–8 (broad region; genes not listed).
- chr17:63,471,604–83,095,122, 654 genes, copy number 6–8 (broad region; genes not listed).
- chr19:13,731,760–24,163,425, 541 genes, copy number 5–9 (broad region; genes not listed).
- chr19:29,606,283–56,078,801, 1,456 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:87,250–32,809,356, 640 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:54,859,688–61,940,617, 127 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:10,328,411–28,228,667, 237 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr21:34,787,801–42,143,453, 154 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr21:44,350,163–46,665,124, 105 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,164. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
